Somatic mutation profile of tumor specimen C3L-02449-01 (aliquot CPT0186720011) from CPTAC case C3L-02449, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 58.2 years (21,243 days).
Specimen C3L-02449-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 440dd4cc-eaa5-4f3a-ae82-754c0fcb4031.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02449-71 (Blood Derived Normal), aliquot CPT0186780002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2894830a-50f7-49c3-bacf-d32474637417

The open-access MAF lists 5,859 somatic variants for this specimen: 4,197 protein-altering or splice-affecting, 921 silent, 741 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3,414, Silent 921, Nonsense Mutation 641, Intron 349, RNA 148, 3'UTR 128, Splice Site 65, Splice Region 51, 5'UTR 50, 5'Flank 38, 3'Flank 28, Frame Shift Ins 11.

Variants (750 of 5,859; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.3507+1G>A p.X1169_splice (on ENST00000265723 / NM_018849.3; = p.X1162_splice on NM_000443.4) | Splice Site (SNP) | VAF 67/285 reads (24%) | catalogued as rs764513998, COSV55941506; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.3826C>T p.R1276* | Nonsense Mutation (SNP) | VAF 23/89 reads (26%) | hotspot (GDC flag); catalogued as COSV61370466; called by muse, mutect2, varscan2
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 73/269 reads (27%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CACNA1E | c.3275C>T p.T1092M | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.855); catalogued as rs1382064469, COSV62393664; ClinVar: likely pathogenic; called by muse, mutect2
- COL4A5 | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 79/279 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1569488426, CM129358, COSV60361481; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DIS3 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 30/126 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs139907646, COSV66705997; called by muse, mutect2, varscan2
- GNAL | c.733C>T p.R245* (on ENST00000269162 / NM_001142339.3; = p.R322* on NM_182978.4) | Nonsense Mutation (SNP) | VAF 21/88 reads (24%) | catalogued as rs1252185897, CM135135, COSV52323513; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAQ | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 34/145 reads (23%) | hotspot (GDC flag); catalogued as COSV54106777, COSV99680195; called by muse, mutect2, varscan2
- IKZF1 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs1245618829, COSV100498631, COSV58784478; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2C | c.13646G>A p.R4549H | Missense Mutation (SNP) | VAF 63/214 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51504408; called by muse, mutect2, varscan2
- KRIT1 | c.1267C>T p.R423* | Nonsense Mutation (SNP) | VAF 34/149 reads (23%) | catalogued as rs886039402, CM022620, COSV60667006; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MANBA | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 42/188 reads (22%) | catalogued as rs121434335, CM024127, COSV56963551, COSV99898471; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 81/396 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2, varscan2
- MMAA | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 44/185 reads (24%) | catalogued as rs1029096863, CM113629, COSV99849569; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTM1 | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 50/291 reads (17%) | catalogued as rs587783828; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.3133C>T p.R1045C | Missense Mutation (SNP) | VAF 93/331 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs45611033, CM086874, COSV62516082; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 100/353 reads (28%) | hotspot (GDC flag); catalogued as rs778405030, CM950845, COSV62197118; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.7348C>T p.R2450* (on ENST00000358273 / NM_001042492.3; = p.R2429* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 46/238 reads (19%) | hotspot (GDC flag); catalogued as rs786202457, CD000998, CM000818, COSV62193225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPHP3 | c.424C>T p.R142* | Nonsense Mutation (SNP) | VAF 28/93 reads (30%) | catalogued as rs771742823, COSV58129232; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PBRM1 | c.2128C>T p.R710* | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | hotspot (GDC flag); catalogued as COSV56260264, COSV56262552; called by muse, mutect2
- PDHA1 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 85/367 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs863224147, CM961098, COSV58825380, COSV58827746; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 22/110 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, varscan2
- PIK3CA | c.333G>T p.K111N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55876538, COSV55894288; called by muse, varscan2
- PIK3CA | c.3073A>G p.T1025A | Missense Mutation (SNP) | VAF 17/74 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs397517202, CM126696, COSV55873252, COSV55911053, COSV55955422; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1042C>T p.R348* (on ENST00000521381 / NM_181523.3; = p.R78* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 32/125 reads (26%) | hotspot (GDC flag); catalogued as rs1057520690, COSV57123475; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 55/256 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- PRLR | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 33/113 reads (29%) | catalogued as rs376188691, COSV51492949; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPRD | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 39/268 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as rs764400127, COSV61926988, COSV61964410; called by muse, mutect2, varscan2
- TFG | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 18/116 reads (16%) | catalogued as rs764959531, COSV53749011; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- USH2A | c.4474G>T p.E1492* | Nonsense Mutation (SNP) | VAF 36/142 reads (25%) | catalogued as rs869312179, CM058338; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 155/523 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766485554, COSV55116456; called by muse, mutect2, varscan2
- ABAT | c.1014C>A p.F338L | Missense Mutation (SNP) | VAF 65/223 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as rs934153114; called by muse, mutect2, varscan2
- ABCA1 | c.4714C>T p.R1572* | Nonsense Mutation (SNP) | VAF 20/383 reads (5%) | catalogued as rs1285576587; called by muse, mutect2
- ABCA10 | c.3668G>T p.R1223I | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52229274; called by muse, mutect2, varscan2
- ABCA12 | c.2851G>A p.E951K (on ENST00000272895 / NM_173076.3; = p.E633K on NM_015657.3) | Missense Mutation (SNP) | VAF 62/240 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as rs1353723813, COSV55948964; called by muse, mutect2, varscan2
- ABCA13 | c.11457G>T p.E3819D | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV71294046; called by muse, mutect2, varscan2
- ABCA4 | c.1344G>T p.M448I | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as CD991545; called by muse, mutect2, varscan2
- ABCA5 | c.60G>T p.K20N | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67016490, COSV67018709; called by muse, mutect2, varscan2
- ABCA6 | c.4801G>T p.E1601* | Nonsense Mutation (SNP) | VAF 20/100 reads (20%) | catalogued as COSV52636877; called by muse, mutect2, varscan2
- ABCA8 | c.3352G>A p.E1118K | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.84); PolyPhen benign (0.026); catalogued as rs768333090, COSV52197981; called by muse, mutect2, varscan2
- ABCA9 | c.2443G>T p.D815Y | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV60623817; called by muse, mutect2, varscan2
- ABCA9 | c.434G>T p.R145I | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as COSV60620849; called by muse, mutect2, varscan2
- ABCB1 | c.2278C>A p.L760I | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); catalogued as COSV99711734; called by muse, mutect2, varscan2
- ABCB11 | c.1117C>A p.L373I | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.2); catalogued as COSV104379459; called by muse, mutect2, varscan2
- ABCB4 | c.3241C>T p.L1081F | Missense Mutation (SNP) | VAF 73/260 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772948456; called by muse, mutect2, varscan2
- ABCB4 | c.1204T>G p.S402A | Missense Mutation (SNP) | VAF 81/328 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.265); catalogued as COSV55938806; called by muse, varscan2
- ABCB4 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 13/236 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV99711373; called by muse, mutect2
- ABCB7 | c.622G>A p.E208K (on ENST00000373394 / NM_001271696.3; = p.E209K on NM_004299.6) | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99504780; called by muse, mutect2, varscan2
- ABCC11 | c.3745G>A p.D1249N | Missense Mutation (SNP) | VAF 47/224 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as rs199710650; called by muse, mutect2, varscan2
- ABCD3 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 130/431 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs759180503; called by muse, mutect2, varscan2
- ABCG5 | c.990G>T p.K330N | Missense Mutation (SNP) | VAF 114/418 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as rs1339151172, COSV99575211; called by muse, varscan2
- ABHD18 | c.379C>A p.L127I | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV66293156; called by muse, mutect2, varscan2
- ABL2 | c.982G>T p.E328* (on ENST00000502732 / NM_007314.4; = p.E313* on NM_005158.5) | Nonsense Mutation (SNP) | VAF 24/127 reads (19%) | catalogued as COSV100772713; called by muse, mutect2, varscan2
- AC004832.3 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 137/560 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs147279727; called by muse, mutect2, varscan2
- ACACA | c.6772C>T p.R2258C | Missense Mutation (SNP) | VAF 96/305 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761713389; called by muse, mutect2, varscan2
- ACACB | c.6124C>T p.P2042S | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV58128172; called by muse, mutect2, varscan2
- ACAN | c.5317C>A p.L1773I | Missense Mutation (SNP) | VAF 115/516 reads (22%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.661); catalogued as rs767359295, COSV61357916, COSV61369764; called by muse, mutect2, varscan2
- ACAT1 | c.164T>G p.F55C | Missense Mutation (SNP) | VAF 78/295 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54920455; called by muse, varscan2
- ACBD6 | c.812C>A p.S271Y | Missense Mutation (SNP) | VAF 87/367 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as rs1186863071, COSV62571867; called by muse, mutect2, varscan2
- ACD | c.154C>A p.L52I | Missense Mutation (SNP) | VAF 67/234 reads (29%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.284); catalogued as COSV54665649, COSV54666110; called by muse, mutect2, varscan2
- ACER3 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 27/124 reads (22%) | catalogued as rs782329790, COSV53598670; called by muse, mutect2, varscan2
- ACOX3 | c.555A>G p.I185M | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.685); catalogued as rs919870228; called by muse, mutect2
- ACOX3 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 42/309 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141372938, COSV99067070; called by muse, mutect2, varscan2
- ACSBG2 | c.18G>T p.K6N | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.015); catalogued as COSV99397265; called by muse, mutect2, varscan2
- ACSBG2 | c.391C>A p.L131I | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.204); catalogued as COSV99397610; called by muse, mutect2, varscan2
- ACSM4 | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV68067891, COSV68069762; called by muse, mutect2, varscan2
- ACTC1 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.947); catalogued as rs538052265; called by muse, varscan2
- ACTN2 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 76/250 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs566860712, COSV63977424; ClinVar: uncertain significance; called by muse, varscan2
- ACTN2 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 54/202 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs761640231, COSV63977686; called by muse, varscan2
- ADAM10 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 15/113 reads (13%) | catalogued as rs1450862420; called by muse, mutect2, varscan2
- ADAM12 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.053); catalogued as rs745765822, COSV100901518, COSV64106233; called by muse, mutect2, varscan2
- ADAM18 | c.2183C>A p.S728* | Nonsense Mutation (SNP) | VAF 27/119 reads (23%) | catalogued as COSV55844091; called by muse, mutect2, varscan2
- ADAM28 | c.216G>T p.L72F | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56099343; called by muse, mutect2, varscan2
- ADAM9 | c.1055A>C p.N352T | Missense Mutation (SNP) | VAF 96/393 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65960188, COSV65962546; called by muse, mutect2, varscan2
- ADAMTS10 | c.3136C>T p.R1046W | Missense Mutation (SNP) | VAF 92/362 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV54353598; called by muse, mutect2, varscan2
- ADAMTS16 | c.1856C>T p.S619L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as rs762449850, COSV56976236; called by muse, mutect2, varscan2
- ADAMTS18 | c.1544A>G p.Y515C | Missense Mutation (SNP) | VAF 91/406 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1227412077; called by muse, mutect2, varscan2
- ADAMTS18 | c.334C>A p.L112I | Missense Mutation (SNP) | VAF 30/314 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746759930; called by muse, mutect2
- ADAMTSL3 | c.3956T>C p.I1319T | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as rs1207663872; called by muse, mutect2, varscan2
- ADCY5 | c.1105A>G p.N369D | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as rs1366013592; called by muse, varscan2
- ADCY8 | c.522C>A p.F174L | Missense Mutation (SNP) | VAF 77/334 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as COSV53895941, COSV53903391; called by muse, mutect2, varscan2
- ADD3 | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs767558945, COSV53321083; called by muse, varscan2
- ADGRA1 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as rs1035149080, COSV66925836; called by muse, mutect2
- ADGRA3 | c.338G>T p.R113L | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV57546319; called by muse, mutect2, varscan2
- ADGRB3 | c.1833C>A p.F611L | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.437); catalogued as COSV65383768; called by muse, mutect2, varscan2
- ADGRF4 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs771530266, COSV51951749, COSV51955542; called by muse, varscan2
- ADGRG2 | c.2491G>T p.D831Y (on ENST00000379869 / NM_001079858.3; = p.D828Y on NM_005756.4) | Missense Mutation (SNP) | VAF 77/294 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61337970; called by muse, mutect2, varscan2
- ADGRG2 | c.2113C>A p.L705I (on ENST00000379869 / NM_001079858.3; = p.L702I on NM_005756.4) | Missense Mutation (SNP) | VAF 110/377 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61337999; called by muse, varscan2
- ADGRG4 | c.5438C>A p.S1813Y | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV54948719, COSV54958946; called by muse, mutect2, varscan2
- ADGRL3 | c.1798C>A p.L600I (on ENST00000506720 / NM_001322402.2; = p.L532I on NM_015236.6) | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.291); catalogued as rs910419173; called by muse, mutect2, varscan2
- ADGRL3 | c.2297-1G>T p.X766_splice (on ENST00000506720 / NM_001322402.2; = p.X698_splice on NM_015236.6) | Splice Site (SNP) | VAF 22/98 reads (22%) | catalogued as COSV72230192; called by muse, varscan2
- ADGRV1 | c.14308C>T p.R4770C | Missense Mutation (SNP) | VAF 61/273 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.232); catalogued as rs970955155; called by muse, mutect2, varscan2
- ADH1C | c.68C>A p.S23Y | Missense Mutation (SNP) | VAF 72/283 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV72463392; called by muse, mutect2, varscan2
- ADH6 | c.1017G>T p.E339D | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV52955169; called by muse, mutect2, varscan2
- ADH7 | c.1136+2T>G p.X379_splice | Splice Site (SNP) | VAF 12/51 reads (24%) | catalogued as COSV52923097; called by muse, mutect2, varscan2
- ADNP2 | c.2243G>A p.R748Q | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.677); catalogued as rs377757808; called by muse, mutect2, varscan2
- ADSS2 | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 36/123 reads (29%) | catalogued as COSV63694640, COSV63695668; called by muse, varscan2
- AF196969.1 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 97/382 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as rs782775797, COSV104370449; called by muse, mutect2, varscan2
- AFF2 | c.3270C>T p.F1090= | Splice Region (SNP) | VAF 44/135 reads (33%) | catalogued as rs371376716, COSV99059882; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AFP | c.1240C>T p.R414* | Nonsense Mutation (SNP) | VAF 70/230 reads (30%) | catalogued as rs374322791; called by muse, varscan2
- AFTPH | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 30/81 reads (37%) | catalogued as COSV53219722; called by muse, varscan2
- AGBL3 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.674); catalogued as rs901299301; called by muse, mutect2
- AGBL5 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 55/187 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs868031509; called by muse, mutect2, varscan2
- AGMO | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs756450306, COSV100693522; called by muse, mutect2, varscan2
- AGPAT3 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV52367458; called by muse, mutect2, varscan2
- AHCTF1 | c.5522C>A p.S1841Y (on ENST00000366508; = p.S1815Y on NM_015446.5) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV100404216; called by mutect2, varscan2
- AIP | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs775850708, COSV54160906; called by muse, mutect2, varscan2
- AKAP12 | c.2818G>T p.E940* | Nonsense Mutation (SNP) | VAF 43/158 reads (27%) | catalogued as COSV99483907; called by muse, mutect2, varscan2
- AKAP6 | c.5141C>T p.S1714L | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs143719716, COSV55208499, COSV55218311; called by muse, mutect2, varscan2
- AKAP9 | c.9994C>T p.R3332* (on ENST00000359028; = p.R3308* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 68/271 reads (25%) | catalogued as rs771217988, COSV62341755; called by muse, mutect2, varscan2
- AKNA | c.2692C>T p.R898C | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.249); catalogued as rs201336367; called by muse, mutect2, varscan2
- AKT3 | c.621T>A p.F207L | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55624178; called by muse, mutect2, varscan2
- AL592490.1 | c.2062G>T p.D688Y | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69425320; called by muse, mutect2
- ALB | c.1031C>A p.A344D | Missense Mutation (SNP) | VAF 70/310 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.374); catalogued as COSV55740720; called by muse, mutect2, varscan2
- ALDOB | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs780442649, COSV66398306; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALMS1 | c.2158G>A p.E720K | Missense Mutation (SNP) | VAF 24/380 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV52506342; called by muse, mutect2
- ALPK2 | c.3046G>A p.E1016K | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs184186856, COSV100864540; called by muse, mutect2, varscan2
- AMBP | c.814G>A p.V272I | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs559236795; called by muse, mutect2, varscan2
- AMD1 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs753517621, COSV64387769; called by muse, mutect2, varscan2
- AMDHD1 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758223660, COSV57137813; called by muse, mutect2, varscan2
- AMPD1 | c.1801C>A p.L601M | Missense Mutation (SNP) | VAF 81/352 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.513); catalogued as COSV62417301; called by muse, mutect2, varscan2
- AMPH | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as rs367689186, COSV57737340; called by muse, mutect2, varscan2
- ANK3 | c.7141G>A p.D2381N | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); catalogued as rs367600332; called by muse, mutect2, varscan2
- ANK3 | c.769C>T p.R257* | Nonsense Mutation (SNP) | VAF 29/140 reads (21%) | catalogued as COSV55050843; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1293G>T p.K431N | Missense Mutation (SNP) | VAF 37/398 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as COSV62008349; called by muse, mutect2, varscan2
- ANKRD31 | c.2458G>T p.E820* | Nonsense Mutation (SNP) | VAF 37/138 reads (27%) | catalogued as COSV57159985; called by muse, mutect2, varscan2
- ANKRD36 | c.1732A>G p.T578A | Missense Mutation (SNP) | VAF 67/278 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.492); catalogued as rs778932380; called by muse, mutect2, varscan2
- ANKRD36C | c.3845C>T p.S1282L | Missense Mutation (SNP) | VAF 42/249 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs762076496; called by muse, varscan2
- ANKRD50 | c.1585C>T p.R529W | Missense Mutation (SNP) | VAF 60/199 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs368187440; called by muse, mutect2, varscan2
- ANKS1B | c.3391C>T p.R1131C (on ENST00000547776 / NM_152788.4; = p.R297C on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs965673606, COSV59124585; called by muse, mutect2, varscan2
- ANKS6 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as rs775835091, COSV62048792; called by muse, mutect2, varscan2
- ANKUB1 | c.982C>A p.L328I | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as COSV67167708; called by muse, mutect2
- ANO4 | c.594C>A p.F198L (on ENST00000392977 / NM_001286615.2; = p.F163L on NM_178826.4) | Missense Mutation (SNP) | VAF 21/320 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV54597694; called by muse, mutect2
- ANO4 | c.2303-1G>T p.X768_splice (on ENST00000392977 / NM_001286615.2; = p.X733_splice on NM_178826.4) | Splice Site (SNP) | VAF 5/28 reads (18%) | catalogued as COSV54615559; called by muse, varscan2
- ANO5 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 18/299 reads (6%) | catalogued as COSV100201415; called by muse, mutect2
- ANO5 | c.696G>T p.K232N | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.931); catalogued as COSV61083318; called by muse, mutect2, varscan2
- ANO6 | c.1532C>T p.T511M | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1324207569; called by muse, mutect2, varscan2
- ANXA7 | c.482C>A p.S161Y | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.069); catalogued as COSV65824429; called by muse, mutect2, varscan2
- ANXA9 | c.807G>T p.K269N | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV64485554; called by muse, mutect2
- AOPEP | c.2069G>T p.R690I (on ENST00000375315 / NM_001193329.1; = p.R591I on NM_032823.5) | Missense Mutation (SNP) | VAF 79/297 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as COSV99950221; called by muse, mutect2, varscan2
- AOPEP | c.*2G>A | Splice Region (SNP) | VAF 8/133 reads (6%) | catalogued as rs1371457553, COSV52988837; called by muse, mutect2
- AOX1 | c.2302G>T p.E768* | Nonsense Mutation (SNP) | VAF 34/134 reads (25%) | catalogued as COSV101022134; called by muse, mutect2, varscan2
- AP000471.1 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 117/486 reads (24%) | catalogued as COSV52451130; called by muse, mutect2, varscan2
- AP1S2 | c.224A>C p.N75T | Missense Mutation (SNP) | VAF 62/267 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100236916; called by muse, mutect2, varscan2
- AP3B2 | c.2844C>A p.F948L (on ENST00000261722; = p.F942L on NM_004644.5) | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV99916294; called by muse, mutect2, varscan2
- AP3M2 | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 39/94 reads (41%) | catalogued as COSV51528181; called by muse, mutect2, varscan2
- AP4E1 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.689); catalogued as rs768086723, COSV55915344; called by muse, mutect2, varscan2
- AP4E1 | c.2509G>A p.D837N | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs754108995; called by muse, varscan2
- APBB1IP | c.997C>A p.L333I | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.709); catalogued as rs796405869; called by muse, mutect2, varscan2
- API5 | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 37/160 reads (23%) | catalogued as COSV66632722; called by muse, mutect2, varscan2
- APOL3 | c.228G>T p.K76N (on ENST00000349314 / NM_145640.2; = p.K5N on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV62579701; called by muse, mutect2, varscan2
- APP | c.2292C>A p.F764L | Missense Mutation (SNP) | VAF 90/395 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1382239795, COSV60994133; called by muse, mutect2, varscan2
- AQP3 | c.483C>A p.F161L | Missense Mutation (SNP) | VAF 74/301 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99955472; called by muse, mutect2, varscan2
- AQP9 | c.90C>A p.F30L | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as COSV54967982; called by muse, mutect2, varscan2
- AQR | c.3052C>T p.R1018* | Nonsense Mutation (SNP) | VAF 28/83 reads (34%) | catalogued as COSV50030477; called by muse, mutect2, varscan2
- AR | c.2571C>A p.F857L | Missense Mutation (SNP) | VAF 63/224 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.975); catalogued as CM000308; called by muse, mutect2, varscan2
- ARFGEF1 | c.3757C>T p.R1253* | Nonsense Mutation (SNP) | VAF 15/63 reads (24%) | catalogued as COSV51604329; called by muse, mutect2, varscan2
- ARFGEF1 | c.1765A>C p.I589L | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.78); catalogued as COSV51607984; called by muse, mutect2, varscan2
- ARFGEF2 | c.5002C>T p.R1668* | Nonsense Mutation (SNP) | VAF 14/338 reads (4%) | catalogued as COSV64211634; called by muse, mutect2
- ARFGEF3 | c.3224C>T p.T1075M | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs753805774; called by muse, mutect2, varscan2
- ARG2 | c.1058G>T p.R353I | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.294); catalogued as rs754618595; called by muse, mutect2, varscan2
- ARHGAP12 | c.1831C>T p.R611C | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs555184668; called by muse, varscan2
- ARHGAP21 | c.3922C>T p.R1308* | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as COSV57604563; called by muse, mutect2, varscan2
- ARHGAP22 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 63/268 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.47); catalogued as rs137922552, COSV50939280, COSV99984423; called by muse, mutect2, varscan2
- ARHGAP24 | c.491G>A p.R164Q (on ENST00000395184 / NM_001025616.3; = p.R71Q on NM_031305.3) | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750510635, COSV99981876; called by muse, mutect2, varscan2
- ARHGAP29 | c.1094A>G p.N365S | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0.014); catalogued as rs776706339; called by muse, mutect2, varscan2
- ARHGAP30 | c.2245G>T p.E749* | Nonsense Mutation (SNP) | VAF 73/318 reads (23%) | catalogued as COSV63515066; called by muse, mutect2, varscan2
- ARHGEF33 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as rs1349767300; called by muse, mutect2, varscan2
- ARID3C | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52406214; called by muse, mutect2, varscan2
- ARID5B | c.1018G>T p.E340* | Nonsense Mutation (SNP) | VAF 41/229 reads (18%) | catalogued as COSV99688806, COSV99690781; called by muse, mutect2, varscan2
- ARID5B | c.1366G>T p.E456* | Nonsense Mutation (SNP) | VAF 33/110 reads (30%) | catalogued as COSV54414410, COSV54415940; called by muse, mutect2, varscan2
- ARID5B | c.2160G>T p.K720N | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); catalogued as COSV104380860; called by muse, mutect2, varscan2
- ARL6IP1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.959); catalogued as rs369888132; called by muse, varscan2
- ARMC4 | c.1868C>T p.T623M | Missense Mutation (SNP) | VAF 86/301 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs375702916; called by muse, mutect2, varscan2
- ARMC8 | c.856C>T p.R286* (on ENST00000469044 / NM_001363941.2; = p.R272* on NM_014154.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 47/178 reads (26%) | catalogued as COSV61767906; called by muse, varscan2
- ARMH3 | c.1507T>G p.L503V | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.863); catalogued as rs575095402; called by muse, mutect2, varscan2
- ARNTL2 | c.1635G>T p.M545I | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs575263444; called by muse, mutect2, varscan2
- ART3 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 9/173 reads (5%) | catalogued as rs1228339524; called by muse, mutect2
- ASB17 | c.844C>A p.L282I | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.165); catalogued as COSV52411198; called by muse, mutect2, varscan2
- ASB7 | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 18/76 reads (24%) | catalogued as COSV60417431; called by muse, mutect2
- ASPM | c.3205G>T p.E1069* | Nonsense Mutation (SNP) | VAF 12/59 reads (20%) | catalogued as rs1184107294; called by muse, mutect2, varscan2
- ASPRV1 | c.572G>C p.S191T | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100208454; called by muse, mutect2, varscan2
- ASXL1 | c.3225G>T p.K1075N | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV60119376; called by muse, mutect2, varscan2
- ASXL2 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 28/106 reads (26%) | catalogued as COSV55453991, COSV55459868; called by muse, mutect2, varscan2
- ASXL3 | c.2267C>T p.S756F | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as COSV52483878; called by muse, mutect2, varscan2
- ATAD2 | c.3955C>A p.L1319I | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.654); catalogued as rs751897630; called by muse, mutect2, varscan2
- ATAD2 | c.3551C>A p.S1184* | Nonsense Mutation (SNP) | VAF 22/70 reads (31%) | catalogued as COSV54885020; called by muse, varscan2
- ATAD2 | c.3499C>T p.R1167C | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs772123752; called by muse, varscan2
- ATAD2B | c.3350G>T p.R1117I | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.211); catalogued as COSV99476886; called by muse, mutect2, varscan2
- ATAD2B | c.2936G>A p.R979H | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53204714; called by muse, varscan2
- ATAD5 | c.2692G>T p.E898* | Nonsense Mutation (SNP) | VAF 11/88 reads (13%) | catalogued as COSV58978676; called by muse, mutect2, varscan2
- ATF6 | c.1714C>T p.R572* | Nonsense Mutation (SNP) | VAF 26/77 reads (34%) | catalogued as rs760001414, COSV63405877; called by muse, mutect2, varscan2
- ATG4A | c.122-1G>T p.X41_splice | Splice Site (SNP) | VAF 13/50 reads (26%) | catalogued as COSV100619488; called by muse, mutect2, varscan2
- ATG4C | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs763043306, COSV58604122; called by muse, mutect2, varscan2
- ATM | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs750280306, COSV53739314; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATM | c.3397G>T p.E1133* | Nonsense Mutation (SNP) | VAF 58/229 reads (25%) | catalogued as COSV53735585, COSV53740955, COSV53775429; called by muse, mutect2, varscan2
- ATP10A | c.2377C>T p.R793W | Missense Mutation (SNP) | VAF 58/220 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs747360622, COSV63512971, COSV63522119; called by muse, mutect2, varscan2
- ATP10A | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.427); catalogued as rs765464148, COSV63514303; called by muse, mutect2, varscan2
- ATP11C | c.1602-1G>T p.X534_splice | Splice Site (SNP) | VAF 24/119 reads (20%) | catalogued as COSV59565289, COSV59566606; called by muse, mutect2, varscan2
- ATP12A | c.204G>T p.E68D | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV99516917; called by muse, mutect2, varscan2
- ATP12A | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1290130064; called by muse, mutect2, varscan2
- ATP13A5 | c.2193G>T p.K731N | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1167129944, COSV100665273, COSV60867694; called by muse, mutect2
- ATP13A5 | c.1923G>T p.K641N | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.102); catalogued as rs928557187, COSV100665011; called by muse, mutect2, varscan2
- ATP13A5 | c.1418G>T p.R473I | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100664961, COSV60872829; called by muse, mutect2, varscan2
- ATP1A2 | c.2562C>T p.I854= | Splice Region (SNP) | VAF 94/311 reads (30%) | catalogued as rs371086182, COSV100767836; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATP5F1C | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | catalogued as rs1436478284, COSV59620786; called by muse, mutect2, varscan2
- ATP6V0A4 | c.805G>T p.D269Y | Missense Mutation (SNP) | VAF 72/460 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59472735; called by muse, mutect2, varscan2
- ATP6V1B1 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 19/319 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs982193032, COSV52268095; called by muse, mutect2
- ATP7A | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.493); catalogued as rs897502448, COSV58450615; called by muse, mutect2, varscan2
- ATP7A | c.1642G>T p.E548* | Nonsense Mutation (SNP) | VAF 95/381 reads (25%) | catalogued as COSV58445162; called by muse, mutect2, varscan2
- ATP8B4 | c.2329G>T p.E777* | Nonsense Mutation (SNP) | VAF 9/185 reads (5%) | catalogued as COSV99464456; called by muse, mutect2
- ATP9A | c.2189C>T p.S730L | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as rs759503719; called by muse, mutect2, varscan2
- ATRX | c.5450G>T p.R1817M | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100970167; called by muse, mutect2, varscan2
- ATXN7L1 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.989); catalogued as rs1302081969; called by muse, mutect2
- AXIN2 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61057896; called by muse, mutect2, varscan2
- B3GALT5 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV58197825; called by muse, mutect2
- BACH1 | c.1897G>T p.E633* | Nonsense Mutation (SNP) | VAF 82/282 reads (29%) | catalogued as rs779746147, COSV54521381; called by muse, mutect2, varscan2
- BBS12 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs928199736, COSV58561273; called by muse, mutect2, varscan2
- BBS12 | c.941G>T p.R314I | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV58563169; called by muse, mutect2, varscan2
- BBS9 | c.797G>T p.R266I | Missense Mutation (SNP) | VAF 94/350 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV54174522; called by muse, mutect2, varscan2
- BCAS2 | c.329C>A p.S110Y | Missense Mutation (SNP) | VAF 47/183 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV65767391; called by muse, mutect2, varscan2
- BCHE | c.1102G>T p.D368Y | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52262346; called by muse, mutect2, varscan2
- BCL11B | c.2653G>A p.D885N (on ENST00000357195 / NM_001282237.2; = p.D814N on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/332 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.787); catalogued as COSV61734563; called by muse, mutect2, varscan2
- BCL2A1 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 44/348 reads (13%) | catalogued as COSV51213543; called by muse, mutect2, varscan2
- BCLAF3 | c.251G>T p.R84I | Missense Mutation (SNP) | VAF 76/239 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV61413873; called by muse, mutect2, varscan2
- BCOR | c.2846C>A p.S949* | Nonsense Mutation (SNP) | VAF 116/423 reads (27%) | catalogued as COSV60722709; called by muse, mutect2, varscan2
- BCR | c.3089C>T p.S1030L | Missense Mutation (SNP) | VAF 119/307 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs760485834; called by muse, mutect2, varscan2
- BDP1 | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 62/225 reads (28%) | catalogued as rs751729367, COSV62432420; called by muse, mutect2, varscan2
- BEND2 | c.1121C>T p.S374L | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs546359357, COSV66215101; called by muse, mutect2, varscan2
- BIRC6 | c.3224G>A p.R1075Q | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70196110; called by muse, mutect2, varscan2
- BIRC6 | c.13084G>A p.E4362K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs753778607, COSV70195621; called by muse, mutect2, varscan2
- BLM | c.1018G>T p.D340Y | Missense Mutation (SNP) | VAF 56/186 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV100756985, COSV61923846; called by muse, mutect2, varscan2
- BLOC1S5 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as COSV55241687; called by muse, mutect2, varscan2
- BMP2 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.04); catalogued as rs201927971, COSV66577064, COSV66578429; called by muse, mutect2
- BMP3 | c.1347C>A p.F449L | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51082268; called by muse, mutect2, varscan2
- BMP4 | c.605C>T p.T202M | Missense Mutation (SNP) | VAF 146/435 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770008356; called by muse, mutect2, varscan2
- BMP5 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 44/161 reads (27%) | catalogued as COSV63706517; called by muse, mutect2, varscan2
- BMP7 | c.813G>T p.Q271H | Missense Mutation (SNP) | VAF 128/482 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV101216142, COSV101216388; called by muse, mutect2, varscan2
- BMP8A | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.019); catalogued as rs778981860; called by mutect2, varscan2
- BRAF | c.1429C>T p.R477* (on ENST00000288602 / NM_001374244.1; = p.R437* on NM_004333.6 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 57/204 reads (28%) | catalogued as rs1249895723, COSV99072590; called by muse, mutect2, varscan2
- BRINP1 | c.1545C>A p.F515L | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV56315925; called by muse, mutect2, varscan2
- BRINP2 | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.382); catalogued as rs778753983, COSV64180016; called by muse, mutect2, varscan2
- BRWD3 | c.4622C>T p.S1541L | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.108); catalogued as COSV64744601; called by muse, mutect2
- BRWD3 | c.233G>A p.R78K | Missense Mutation (SNP) | VAF 67/229 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as rs957439454, COSV100955522; called by muse, mutect2, varscan2
- BTNL2 | c.732T>G p.A244= | Splice Region (SNP) | VAF 17/73 reads (23%) | catalogued as rs1346936310; called by muse, varscan2
- C10orf105 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs979991212, COSV56465879; called by muse, mutect2, varscan2
- C12orf4 | c.908G>T p.R303I | Missense Mutation (SNP) | VAF 57/209 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.664); catalogued as COSV54206233; called by muse, mutect2, varscan2
- C12orf42 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 53/252 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.948); catalogued as COSV104408406; called by muse, varscan2
- C14orf39 | c.1762del p.*588Efs*16 | Frame Shift Del (DEL) | VAF 22/84 reads (26%) | catalogued as rs780875081; called by mutect2, varscan2
- C15orf39 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 58/251 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1232154902; called by muse, mutect2, varscan2
- C16orf72 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 19/327 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs1366213938, COSV59916594; called by muse, mutect2
- C16orf82 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.58); catalogued as rs1329725127; called by muse, mutect2
- C16orf96 | c.2258G>T p.R753I | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs1183521995, COSV104437263; called by muse, mutect2, varscan2
- C18orf54 | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55618161; called by muse, mutect2, varscan2
- C1QL1 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 114/491 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.358); catalogued as rs1349271970; called by muse, mutect2, varscan2
- C2orf16 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs770708739, COSV101284409; called by muse, mutect2, varscan2
- C2orf16 | c.2306A>G p.N769S | Missense Mutation (SNP) | VAF 48/213 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.356); catalogued as COSV62675763; called by muse, mutect2, varscan2
- C2orf50 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs141429224, COSV67510550; called by muse, mutect2, varscan2
- C3 | c.4951G>A p.A1651T | Missense Mutation (SNP) | VAF 32/368 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs756442896; called by muse, mutect2
- C3orf20 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 77/222 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.343); catalogued as rs768861528, COSV53782331, COSV99513234; called by muse, mutect2, varscan2
- C3orf62 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 38/188 reads (20%) | catalogued as rs755185861, COSV100542893; called by muse, varscan2
- C4BPA | c.1342G>T p.E448* | Nonsense Mutation (SNP) | VAF 28/91 reads (31%) | catalogued as rs1215951903, COSV65535588; called by muse, mutect2, varscan2
- C4orf45 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs755417558, COSV101465064; called by muse, mutect2, varscan2
- C5orf34 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs751051116, COSV60931222; called by muse, mutect2, varscan2
- C7orf25 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs1003393016, COSV63273458; called by muse, mutect2, varscan2
- C8orf48 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 45/195 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1472627562, COSV99813558; called by muse, mutect2, varscan2
- CABIN1 | c.1245G>T p.M415I | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99572637; called by muse, mutect2, varscan2
- CABLES1 | c.951G>T p.K317N (on ENST00000256925 / NM_001100619.2; = p.K52N on NM_138375.2) | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV56934170; called by muse, mutect2, varscan2
- CACNA1B | c.5738G>A p.R1913Q | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.32); catalogued as rs779631598, COSV53125232; called by mutect2, varscan2
- CACNA1B | c.6152A>G p.H2051R | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.085); catalogued as COSV53125746; called by muse, mutect2, varscan2
- CACNA1H | c.4444C>T p.R1482* | Nonsense Mutation (SNP) | VAF 46/150 reads (31%) | catalogued as rs763390819, COSV61991971; called by muse, mutect2, varscan2
- CACNA1S | c.2708G>A p.R903Q | Missense Mutation (SNP) | VAF 86/318 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as rs1452713683; called by muse, mutect2, varscan2
- CACNA2D3 | c.1715G>T p.R572I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99868378; called by muse, mutect2, varscan2
- CALCR | c.708G>T p.K236N (on ENST00000649521 / NM_001164737.2; = p.K220N on NM_001742.4) | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64013261; called by muse, mutect2, varscan2
- CAPN6 | c.113C>A p.S38Y | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100136965; called by muse, mutect2, varscan2
- CAPRIN2 | c.401G>T p.R134I | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51830358; called by muse, mutect2, varscan2
- CARD6 | c.1089G>T p.E363D | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.73); catalogued as rs779331588; called by muse, mutect2, varscan2
- CASP4 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 63/294 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as rs1030418546, COSV67744181, COSV67744639; called by muse, mutect2, varscan2
- CASP8 | c.412-1G>T p.X138_splice (on ENST00000432109 / NM_033355.3; = p.X170_splice on NM_001228.4) | Splice Site (SNP) | VAF 83/339 reads (24%) | catalogued as COSV51845122, COSV51859458; called by muse, mutect2, varscan2
- CATSPERB | c.3010C>A p.L1004I | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as rs1431530206, COSV56422881; called by muse, mutect2, varscan2
- CATSPERD | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776962512, COSV101062331; called by muse, varscan2
- CATSPERE | c.1627T>G p.F543V | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV63679951; called by muse, mutect2, varscan2
- CAVIN4 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146923040; called by muse, mutect2, varscan2
- CCDC122 | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 24/96 reads (25%) | catalogued as COSV55708664, COSV99865881; called by muse, varscan2
- CCDC144A | c.1588G>T p.E530* | Nonsense Mutation (SNP) | VAF 15/92 reads (16%) | catalogued as COSV100138629; called by mutect2, varscan2
- CCDC151 | c.1784C>T p.S595F | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.821); catalogued as COSV100710644; called by muse, mutect2, varscan2
- CCDC168 | c.19382C>A p.S6461Y | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV100487781; called by muse, mutect2, varscan2
- CCDC168 | c.15589C>T p.P5197S | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs1169932340; called by muse, mutect2, varscan2
- CCDC168 | c.14038G>A p.A4680T | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.14); catalogued as rs1443775775; called by muse, mutect2
- CCDC168 | c.8540G>A p.R2847Q | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.219); catalogued as rs190785971; called by muse, mutect2, varscan2
- CCDC168 | c.6251G>A p.G2084E | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as COSV70556033; called by muse, mutect2
- CCDC168 | c.5323G>T p.E1775* | Nonsense Mutation (SNP) | VAF 36/158 reads (23%) | catalogued as COSV70554845; called by muse, mutect2, varscan2
- CCDC171 | c.2718G>T p.K906N | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV52633945, COSV99899566; called by muse, mutect2
- CCDC173 | c.1408G>T p.E470* | Nonsense Mutation (SNP) | VAF 42/173 reads (24%) | catalogued as COSV53643002; called by muse, mutect2, varscan2
- CCDC173 | c.1033G>T p.D345Y | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1431528992, COSV71653193; called by muse, mutect2, varscan2
- CCDC186 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs759611860; called by muse, mutect2, varscan2
- CCDC22 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 83/335 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100873058, COSV66051024; called by muse, mutect2, varscan2
- CCDC30 | c.658C>T p.R220* (on ENST00000340612; = p.R177* on NM_001080850.3) | Nonsense Mutation (SNP) | VAF 11/194 reads (6%) | catalogued as COSV59607444; called by muse, mutect2
- CCDC39 | c.1796G>A p.R599Q | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs541958184, COSV56478424; called by muse, mutect2, varscan2
- CCDC60 | c.281G>T p.R94I | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV59544341; called by muse, mutect2, varscan2
- CCDC60 | c.618G>T p.Q206H | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV59552429; called by muse, mutect2, varscan2
- CCDC60 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV59542305; called by muse, mutect2, varscan2
- CCDC82 | c.986C>A p.S329Y | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV53594441; called by muse, mutect2, varscan2
- CCDC88A | c.5410C>T p.R1804C (on ENST00000436346 / NM_001365480.1; = p.R1776C on NM_018084.5) | Missense Mutation (SNP) | VAF 117/414 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs765138609, COSV99710275; called by muse, varscan2
- CCDC88A | c.2011G>T p.E671* | Nonsense Mutation (SNP) | VAF 7/95 reads (7%) | catalogued as COSV55068743; called by muse, mutect2
- CCDC91 | c.461G>T p.R154I | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs774693971, COSV60347182; called by muse, mutect2, varscan2
- CCER1 | c.1066G>T p.E356* | Nonsense Mutation (SNP) | VAF 35/125 reads (28%) | catalogued as COSV62646863; called by muse, mutect2, varscan2
- CCNA1 | c.645T>G p.I215M | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1441198707; called by muse, mutect2
- CCNA1 | c.1244C>A p.S415* | Nonsense Mutation (SNP) | VAF 38/117 reads (32%) | catalogued as COSV55221943; called by muse, mutect2, varscan2
- CCNB3 | c.696G>T p.K232N | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV52072145, COSV99328841; called by muse, mutect2, varscan2
- CCNT1 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 49/140 reads (35%) | catalogued as COSV56065445; called by muse, mutect2, varscan2
- CCNYL1 | c.977C>A p.S326Y (on ENST00000295414 / NM_001330218.2; = p.S256Y on NM_152523.2) | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54942110; called by muse, mutect2, varscan2
- CCR3 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.846); catalogued as rs1043285757, COSV100656740, COSV62463212; called by muse, mutect2, varscan2
- CCR5 | c.341C>A p.S114Y | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV52752284; called by muse, mutect2, varscan2
- CCT5 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 95/349 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV54725515; called by muse, mutect2, varscan2
- CD1D | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 80/331 reads (24%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.997); catalogued as COSV63810023; called by muse, mutect2, varscan2
- CD2AP | c.721C>A p.P241T | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs756161725, COSV63759211; called by muse, mutect2
- CD36 | c.245A>G p.N82S | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as COSV59213986; called by muse, mutect2, varscan2
- CD36 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs141475532; called by muse, mutect2, varscan2
- CD58 | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 44/172 reads (26%) | catalogued as COSV59841443; called by muse, mutect2, varscan2
- CD68 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.888); catalogued as rs148674312; called by muse, mutect2
- CDC16 | c.1102C>A p.H368N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52960940; called by muse, varscan2
- CDC20B | c.854G>T p.G285V | Missense Mutation (SNP) | VAF 64/295 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57055129; called by muse, mutect2, varscan2
- CDH13 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.436); catalogued as rs377210458, CM112950; called by muse, mutect2, varscan2
- CDH23 | c.6340G>A p.D2114N | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs977083222; called by muse, mutect2
- CDH8 | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as rs1055288839, COSV54849423; called by muse, varscan2
- CDK5RAP1 | c.1291G>T p.E431* (on ENST00000357886 / NM_001365728.1; = p.E417* on NM_016082.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as COSV59426587; called by muse, mutect2, varscan2
- CDK5RAP2 | c.5602C>T p.R1868W | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141534162; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 108/438 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1343728654, COSV62574034; called by muse, mutect2, varscan2
- CDK8 | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV101037623; called by muse, varscan2
- CECR2 | c.477C>A p.F159L | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV52841089; called by muse, mutect2, varscan2
- CENPE | c.3140C>A p.S1047Y | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54379591; called by muse, mutect2, varscan2
- CENPF | c.2785G>T p.E929* | Nonsense Mutation (SNP) | VAF 17/66 reads (26%) | catalogued as rs867811383; called by muse, mutect2, varscan2
- CEP104 | c.277C>T p.R93* | Nonsense Mutation (SNP) | VAF 37/135 reads (27%) | catalogued as rs145420390, COSV65511801; called by muse, mutect2, varscan2
- CEP128 | c.1695G>T p.E565D | Missense Mutation (SNP) | VAF 61/263 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV55368272; called by muse, mutect2, varscan2
- CEP128 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.127); catalogued as rs945816133, COSV53675651; called by muse, mutect2, varscan2
- CEP135 | c.3347G>A p.R1116Q | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs191813321; called by muse, mutect2, varscan2
- CEP295 | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 16/73 reads (22%) | catalogued as COSV100292042; called by muse, mutect2
- CEP350 | c.4873C>T p.R1625* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | catalogued as rs1181129362, COSV62601953; called by muse, mutect2, varscan2
- CEP350 | c.9028C>T p.R3010* | Nonsense Mutation (SNP) | VAF 18/83 reads (22%) | catalogued as COSV62604233; called by muse, mutect2, varscan2
- CEP83 | c.1531C>T p.R511* | Nonsense Mutation (SNP) | VAF 35/153 reads (23%) | catalogued as rs1162641847, COSV60406547; called by muse, mutect2, varscan2
- CEP83 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377256366; called by muse, mutect2, varscan2
- CEP85L | c.341T>G p.L114R | Missense Mutation (SNP) | VAF 56/241 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.033); catalogued as COSV63821769; called by muse, mutect2, varscan2
- CEP89 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 52/275 reads (19%) | catalogued as rs752399986, COSV59867478; called by muse, mutect2, varscan2
- CEP97 | c.1049C>A p.S350Y | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV59123345; called by muse, mutect2, varscan2
- CES1 | c.1108G>A p.E370K (on ENST00000361503 / NM_001025194.2; = p.E369K on NM_001266.5) | Missense Mutation (SNP) | VAF 82/384 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.65); catalogued as rs185780477, COSV100828576; called by muse, varscan2
- CFAP20 | c.203C>T p.T68M | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs112723051; called by muse, mutect2, varscan2
- CFAP36 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV59116539; called by muse, mutect2, varscan2
- CFAP46 | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1022459187; called by muse, mutect2, varscan2
- CFAP47 | c.9012G>T p.K3004N | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0.012); catalogued as COSV66216886; called by muse, mutect2, varscan2
- CFAP47 | c.9361G>T p.E3121* | Nonsense Mutation (SNP) | VAF 41/133 reads (31%) | catalogued as COSV66216932; called by muse, mutect2, varscan2
- CFAP54 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 79/293 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as rs759335147, COSV54352063; called by muse, mutect2, varscan2
- CFAP54 | c.1345G>T p.E449* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100127603; called by muse, mutect2, varscan2
- CFAP54 | c.4267G>T p.D1423Y | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.651); catalogued as COSV101598505; called by mutect2, varscan2
- CFAP54 | c.6326G>T p.R2109I | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV61571753; called by muse, mutect2, varscan2
- CFAP54 | c.8976G>T p.E2992D | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1057391279; called by muse, mutect2, varscan2
- CFAP58 | c.1540G>T p.D514Y | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV63832669; called by muse, mutect2, varscan2
- CFAP58 | c.2065G>T p.E689* | Nonsense Mutation (SNP) | VAF 14/153 reads (9%) | catalogued as rs1467834668; called by muse, mutect2
- CFAP61 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs115295521, COSV55631172; called by muse, mutect2, varscan2
- CFAP61 | c.2179G>T p.D727Y | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55632536, COSV99845313; called by muse, mutect2, varscan2
- CFAP70 | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 18/146 reads (12%) | catalogued as rs199587364, COSV60283539; called by muse, mutect2, varscan2
- CFH | c.2503G>T p.V835L | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.127); catalogued as rs1470614367, CM045280; called by muse, mutect2, varscan2
- CFH | c.2603T>G p.I868S | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.053); catalogued as rs547338983; called by muse, mutect2, varscan2
- CHAMP1 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs371511810; called by muse, mutect2, varscan2
- CHD4 | c.1244C>T p.S415L (on ENST00000357008 / NM_001363606.2; = p.S428L on NM_001273.5) | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs147387698, COSV58901126; called by muse, mutect2, varscan2
- CHERP | c.2489C>T p.S830L | Missense Mutation (SNP) | VAF 53/193 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as rs371270066; called by muse, mutect2, varscan2
- CHIA | c.1399G>A p.D467N (on ENST00000343320; = p.D359N on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.161); catalogued as rs763851350; called by muse, mutect2, varscan2
- CHL1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.035); catalogued as rs754718767, COSV56598549; called by muse, mutect2
- CHL1 | c.3496G>A p.E1166K (on ENST00000397491 / NM_001253387.1; = p.E1182K on NM_006614.4) | Missense Mutation (SNP) | VAF 71/261 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.722); catalogued as rs374897001, COSV56601533; called by muse, mutect2, varscan2
- CHODL | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs199891121, COSV54733872; called by muse, varscan2
- CHP1 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as rs767999244, COSV58156978; called by muse, mutect2, varscan2
- CHRM4 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.538); catalogued as rs200901598; called by mutect2, varscan2
- CHRNA4 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 140/515 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1352017376; called by muse, varscan2
- CHRNA5 | c.1062G>T p.K354N | Missense Mutation (SNP) | VAF 55/337 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.751); catalogued as COSV55140666; called by muse, mutect2, varscan2
- CHRNA6 | c.764C>A p.S255* | Nonsense Mutation (SNP) | VAF 23/220 reads (10%) | catalogued as COSV52379593; called by muse, varscan2
- CHRNB3 | c.1054C>A p.H352N | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV51494919; called by muse, mutect2, varscan2
- CHST11 | c.983C>T p.T328M | Missense Mutation (SNP) | VAF 17/255 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs887814138; called by muse, mutect2
- CHSY3 | c.1799C>A p.S600Y | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.969); catalogued as rs1179067967, COSV59274179, COSV59286369; called by muse, mutect2, varscan2
- CHSY3 | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0.015); catalogued as COSV59289094; called by muse, mutect2, varscan2
- CIP2A | c.1927C>A p.L643I | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99842964; called by muse, mutect2, varscan2
- CIR1 | c.673C>A p.L225I | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100564876; called by muse, mutect2, varscan2
- CIT | c.5257G>A p.E1753K | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs759976682; called by muse, mutect2, varscan2
- CKAP4 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs773178493, COSV65172465; called by muse, mutect2
- CLASP1 | c.4087C>T p.R1363* | Nonsense Mutation (SNP) | VAF 27/101 reads (27%) | catalogued as COSV55313295; called by muse, mutect2, varscan2
- CLCA4 | c.209G>T p.R70I | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV55370104; called by muse, mutect2, varscan2
- CLCN1 | c.257C>A p.S86Y | Missense Mutation (SNP) | VAF 25/345 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as COSV100578303, COSV58373315; called by muse, mutect2
- CLCN3 | c.1112A>G p.N371S | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.145); catalogued as rs1195330377; called by muse, mutect2, varscan2
- CLCN5 | c.2230C>A p.L744I | Missense Mutation (SNP) | VAF 54/237 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV56583170; called by muse, mutect2, varscan2
- CLHC1 | c.976C>T p.R326* | Nonsense Mutation (SNP) | VAF 51/202 reads (25%) | catalogued as rs753530709, COSV68464143; called by muse, mutect2, varscan2
- CLPX | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 16/93 reads (17%) | catalogued as COSV55647152; called by muse, mutect2, varscan2
- CLSTN3 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 55/206 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs781061270, COSV56936133; called by muse, mutect2, varscan2
- CLTA | c.697C>T p.R233C (on ENST00000242285 / NM_007096.4; = p.R203C on NM_001833.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99643512; called by muse, mutect2, varscan2
- CLUL1 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 78/285 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.414); catalogued as rs527661052, COSV58111689; called by muse, mutect2, varscan2
- CMA1 | c.590C>A p.S197Y | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1462507754; called by muse, mutect2
- CMAS | c.484C>T p.R162* | Nonsense Mutation (SNP) | VAF 35/154 reads (23%) | catalogued as rs1223698463, COSV57556874; called by muse, mutect2, varscan2
- CMYA5 | c.2905G>T p.E969* | Nonsense Mutation (SNP) | VAF 51/188 reads (27%) | catalogued as COSV101483799; called by muse, mutect2, varscan2
- CNGA2 | c.483-1G>A p.X161_splice | Splice Site (SNP) | VAF 27/90 reads (30%) | catalogued as COSV61706182; called by muse, mutect2, varscan2
- CNGB3 | c.948C>A p.F316L | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.14); catalogued as rs764146474, COSV60685653, COSV60687422; called by muse, mutect2, varscan2
- CNGB3 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 116/393 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs752014086, COSV60695307; called by muse, mutect2, varscan2
- CNR1 | c.1339G>T p.E447* | Nonsense Mutation (SNP) | VAF 67/234 reads (29%) | catalogued as COSV100759279; called by muse, mutect2, varscan2
- CNTN1 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 27/207 reads (13%) | catalogued as COSV61635747; called by muse, mutect2, varscan2
- CNTNAP4 | c.191G>T p.R64I | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100271146; called by muse, mutect2, varscan2
- CNTNAP4 | c.2413C>A p.H805N | Missense Mutation (SNP) | VAF 52/205 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56695783; called by muse, mutect2, varscan2
- CNTNAP5 | c.363A>C p.K121N | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV70478704; called by muse, mutect2
- COG6 | c.902C>A p.S301Y | Missense Mutation (SNP) | VAF 18/376 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62995209; called by muse, mutect2
- COL10A1 | c.1722T>G p.I574M | Missense Mutation (SNP) | VAF 139/552 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV54573226; called by muse, mutect2, varscan2
- COL11A1 | c.4396G>A p.E1466K | Missense Mutation (SNP) | VAF 33/247 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs866783525; called by muse, mutect2, varscan2
- COL11A1 | c.1198G>T p.E400* | Nonsense Mutation (SNP) | VAF 55/165 reads (33%) | catalogued as COSV62187140, COSV62197346; called by muse, mutect2, varscan2
- COL11A2 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 148/497 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV59495501; called by muse, mutect2, varscan2
- COL12A1 | c.8765G>A p.R2922K | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59409561; called by muse, mutect2
- COL12A1 | c.847G>T p.E283* | Nonsense Mutation (SNP) | VAF 63/231 reads (27%) | catalogued as COSV59390633; called by muse, mutect2, varscan2
- COL14A1 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV52848487; called by muse, mutect2
- COL1A1 | c.3301G>A p.E1101K | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs867628651; called by muse, mutect2, varscan2
- COL21A1 | c.1528C>T p.R510* | Nonsense Mutation (SNP) | VAF 54/230 reads (23%) | catalogued as rs749557286, COSV55155216; called by muse, mutect2, varscan2
- COL22A1 | c.4758G>T p.E1586D | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV57346977; called by muse, mutect2
- COL24A1 | c.2863C>T p.P955S | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as rs1407358772; called by muse, mutect2, varscan2
- COL28A1 | c.396C>A p.F132L | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV68082785; called by muse, mutect2, varscan2
- COL4A6 | c.4952G>A p.S1651N | Missense Mutation (SNP) | VAF 71/245 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs146123040; called by muse, mutect2, varscan2
- COL5A1 | c.4748C>T p.T1583M | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.474); catalogued as rs375076580; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- COL5A1 | c.5314G>A p.E1772K | Missense Mutation (SNP) | VAF 71/312 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs759042440, COSV65669215; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A2 | c.4358G>A p.R1453Q | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); catalogued as rs149064715; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 18/381 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55099731, COSV55105007, COSV99799667; called by muse, mutect2
- COL6A5 | c.4909G>T p.D1637Y | Missense Mutation (SNP) | VAF 59/252 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV55211638; called by muse, mutect2, varscan2
- COL6A6 | c.6657C>A p.F2219L | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as COSV62035722; called by muse, mutect2, varscan2
- COP1 | c.1032G>T p.K344N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.966); catalogued as COSV58165439; called by muse, mutect2, varscan2
- COQ4 | c.600C>A p.F200L | Missense Mutation (SNP) | VAF 87/287 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55957176; called by muse, mutect2, varscan2
- COQ8B | c.583C>A p.L195I | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.373); catalogued as rs1270207473; called by muse, mutect2
- COQ9 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 94/401 reads (23%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.775); catalogued as rs774033422, COSV52647487; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CORO1C | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV54594022; called by muse, mutect2, varscan2
- COX4I1 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs779831701; called by muse, mutect2
- COX6B1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.119); catalogued as rs765762226, COSV99877040; called by muse, mutect2, varscan2
- CP | c.2705G>T p.R902I | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV99224055; called by muse, mutect2
- CPED1 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as rs1446286819; called by muse, mutect2
- CPOX | c.1180G>T p.E394* | Nonsense Mutation (SNP) | VAF 24/152 reads (16%) | catalogued as COSV99939134; called by muse, mutect2, varscan2
- CPS1 | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV51827428; called by muse, mutect2
- CPXM1 | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66045245; called by muse, mutect2, varscan2
- CPXM2 | c.563G>T p.R188I | Missense Mutation (SNP) | VAF 59/235 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as COSV53868850; called by muse, mutect2, varscan2
- CPZ | c.1200G>T p.K400N (on ENST00000360986 / NM_001014447.3; = p.K389N on NM_003652.3) | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs543182051; called by mutect2, varscan2
- CR1 | c.4465C>T p.R1489* | Nonsense Mutation (SNP) | VAF 26/119 reads (22%) | catalogued as rs778591697, COSV65456307; called by muse, mutect2, varscan2
- CRB1 | c.2592C>A p.F864L | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs986038900, COSV66329292, COSV66331692; called by muse, mutect2, varscan2
- CREBBP | c.3323C>T p.S1108L | Missense Mutation (SNP) | VAF 132/441 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52114165, COSV52118821; called by muse, mutect2, varscan2
- CRHR1 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.487); catalogued as COSV53279579; called by muse, mutect2, varscan2
- CRISPLD1 | c.881C>A p.S294Y | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as COSV51546581; called by muse, mutect2, varscan2
- CRTAM | c.179T>A p.L60* | Nonsense Mutation (SNP) | VAF 21/55 reads (38%) | catalogued as rs777836120, COSV57069971, COSV99912143; called by muse, mutect2, varscan2
- CSMD1 | c.4317C>A p.F1439L (on ENST00000520002; = p.F1438L on NM_033225.6) | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.68); catalogued as COSV59298436; called by muse, mutect2, varscan2
- CSMD1 | c.2831C>A p.S944Y (on ENST00000520002; = p.S943Y on NM_033225.6) | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100150590, COSV100152358; called by muse, mutect2, varscan2
- CSMD3 | c.5512G>T p.E1838* (on ENST00000297405 / NM_001363185.1; = p.E1734* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 60/250 reads (24%) | catalogued as COSV52126511, COSV52239165, COSV52313526; called by muse, mutect2, varscan2
- CSMD3 | c.2991G>T p.K997N (on ENST00000297405 / NM_001363185.1; = p.K893N on NM_052900.3) | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); catalogued as rs760360706, COSV104398729; called by muse, mutect2, varscan2
- CSMD3 | c.2551C>A p.Q851K (on ENST00000297405 / NM_001363185.1; = p.Q747K on NM_052900.3) | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.993); catalogued as COSV52178509; called by muse, mutect2, varscan2
- CSMD3 | c.1419C>A p.I473= (on ENST00000297405 / NM_001363185.1; = p.I369= on NM_052900.3) | Splice Region (SNP) | VAF 22/152 reads (14%) | catalogued as rs769731876, COSV52091242, COSV99851147; called by muse, mutect2, varscan2
- CSPP1 | c.1345G>T p.D449Y (on ENST00000676605; = p.D408Y on NM_024790.6) | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.242); catalogued as rs1393837926, COSV51580477; called by muse, mutect2, varscan2
- CSPP1 | c.1658G>A p.R553Q (on ENST00000676605; = p.R512Q on NM_024790.6) | Missense Mutation (SNP) | VAF 80/319 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.895); catalogued as rs778430027, COSV51584422; called by muse, mutect2, varscan2
- CST11 | c.348C>A p.F116L (on ENST00000377009 / NM_130794.2; = p.F81L on NM_080830.3) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV100983558; called by muse, mutect2, varscan2
- CST2 | c.252C>A p.F84L | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.131); catalogued as COSV59030744; called by muse, varscan2
- CTAGE1 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 70/280 reads (25%) | catalogued as COSV66942860; called by muse, mutect2, varscan2
- CTBP2 | c.357C>T p.L119= | Splice Region (SNP) | VAF 9/63 reads (14%) | catalogued as rs111629462; called by mutect2, varscan2
- CTBS | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs148319034; called by muse, mutect2, varscan2
- CTCF | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50464414, COSV99864989; called by muse, mutect2, varscan2
- CTNNA1 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.849); catalogued as rs192686066; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNA2 | c.1756G>A p.A586T | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.079); catalogued as rs778479901, COSV58165297; called by muse, mutect2, varscan2
- CTNND1 | c.2271G>T p.K757N (on ENST00000399050 / NM_001085458.2; = p.K751N on NM_001331.3) | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs894225352, COSV62382086; called by muse, mutect2, varscan2
- CTNND1 | c.2452G>T p.E818* (on ENST00000399050 / NM_001085458.2; = p.E812* on NM_001331.3) | Nonsense Mutation (SNP) | VAF 16/77 reads (21%) | catalogued as COSV62384572; called by muse, mutect2, varscan2
- CTSF | c.1038G>T p.K346N | Missense Mutation (SNP) | VAF 80/241 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.424); catalogued as COSV100074273; called by muse, mutect2, varscan2
- CTSV | c.872C>T p.S291L | Missense Mutation (SNP) | VAF 46/230 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.396); catalogued as rs771264161, COSV52344711; called by muse, mutect2, varscan2
- CUBN | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 18/407 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs1454795883; called by muse, mutect2
- CUL3 | c.1270G>T p.E424* | Nonsense Mutation (SNP) | VAF 12/68 reads (18%) | catalogued as COSV104388443, COSV52364003; called by muse, mutect2, varscan2
- CUL4B | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as rs1186348723, COSV60684728, COSV60685982; called by muse, mutect2, varscan2
- CUX2 | c.2693C>A p.T898K | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99919901; called by muse, mutect2, varscan2
- CXCL1 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67611532; called by muse, mutect2, varscan2
- CXXC4 | c.737C>A p.S246* | Nonsense Mutation (SNP) | VAF 34/152 reads (22%) | catalogued as COSV67297195; called by muse, mutect2, varscan2
- CXorf38 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs769007634; called by muse, mutect2, varscan2
- CYFIP1 | c.1438G>A p.V480I | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs760215233; called by muse, mutect2, varscan2
- CYLC2 | c.14G>T p.R5I | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs956648077, COSV66336380; called by muse, mutect2, varscan2
- CYP11A1 | c.1210C>A p.L404I | Missense Mutation (SNP) | VAF 81/331 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.239); catalogued as rs1321165216; called by muse, mutect2, varscan2
- CYP19A1 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 59/218 reads (27%) | catalogued as COSV53062640; called by muse, mutect2, varscan2
- CYP27C1 | c.95G>T p.R32I | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100079991, COSV58866752; called by muse, mutect2, varscan2
- CYP2A13 | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 94/340 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs267605496, COSV57837112; called by muse, mutect2, varscan2
- CYP4A11 | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767632502; called by muse, mutect2
- CYP4A22 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.192); catalogued as rs373881337; called by muse, mutect2
- CYP4A22 | c.474C>A p.Y158* | Nonsense Mutation (SNP) | VAF 19/120 reads (16%) | catalogued as rs2758715, COSV99595467; called by muse, mutect2, varscan2
- CYP4F12 | c.980T>C p.F327S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1289845756; called by muse, mutect2, varscan2
- CYP4X1 | c.1302G>T p.E434D | Missense Mutation (SNP) | VAF 13/230 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.253); catalogued as COSV64150409; called by muse, mutect2
- CYP8B1 | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as rs1033043019, COSV60226217; called by muse, varscan2
- CYRIB | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs757439011, COSV101309975; called by muse, mutect2, varscan2
- DAB2 | c.1787G>A p.S596N | Missense Mutation (SNP) | VAF 92/346 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.159); catalogued as rs769397074; called by muse, mutect2, varscan2
- DAB2 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs374921039; called by muse, varscan2
- DAND5 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 62/182 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs748806881, COSV57684082; called by muse, mutect2, varscan2
- DAPK1 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.698); catalogued as rs930286884, COSV63785157; called by muse, mutect2, varscan2
- DAW1 | c.1004G>T p.R335I | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.026); catalogued as COSV59366530, COSV59369610; called by muse, mutect2, varscan2
- DBNL | c.743G>A p.R248Q (on ENST00000448521 / NM_001014436.3; = p.R249Q on NM_014063.7) | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs747090602, COSV51977578; called by muse, mutect2, varscan2
- DCAF1 | c.3848G>A p.R1283Q | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60046385; called by muse, mutect2, varscan2
- DCAF1 | c.828G>T p.E276D | Missense Mutation (SNP) | VAF 19/464 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV60044225; called by muse, mutect2
- DCAF5 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.793); catalogued as rs757111344; called by muse, mutect2, varscan2
- DCAF8L1 | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 38/287 reads (13%) | catalogued as COSV101491364; called by muse, mutect2, varscan2
- DCAF8L2 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 25/251 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV70548728; called by muse, mutect2, varscan2
- DCC | c.1981C>T p.R661* | Nonsense Mutation (SNP) | VAF 83/255 reads (33%) | catalogued as COSV59088081; called by muse, mutect2, varscan2
- DCK | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs370045223; called by muse, mutect2, varscan2
- DCSTAMP | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV52580792; called by muse, mutect2, varscan2
- DCT | c.1490G>T p.R497I | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV100986273; called by muse, mutect2, varscan2
- DDB1 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as rs141900083; called by muse, mutect2, varscan2
- DDX10 | c.926G>T p.R309I | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV59433114; called by muse, mutect2, varscan2
- DDX20 | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 19/85 reads (22%) | catalogued as rs1462330675, COSV63830952; called by muse, mutect2
- DDX25 | c.1045C>T p.R349* | Nonsense Mutation (SNP) | VAF 30/94 reads (32%) | catalogued as rs1336325971, COSV54990370; called by muse, mutect2
- DDX3X | c.157G>A p.D53N (on ENST00000399959; = p.D54N on NM_001356.5) | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as rs1187201543; called by muse, mutect2, varscan2
- DDX42 | c.2090C>T p.T697M | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as rs1343472038, COSV100835029; called by muse, mutect2, varscan2
- DDX50 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.379); catalogued as COSV65291862; called by muse, mutect2
- DDX59 | c.1430C>T p.S477L | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as rs536485578; called by muse, mutect2, varscan2
- DDX60 | c.8G>T p.R3I | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.011); catalogued as COSV67095857; called by muse, mutect2, varscan2
- DEFB108B | c.72C>A p.F24L | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs967106082, COSV60822670; called by muse, mutect2
- DEFB129 | c.62T>G p.F21C | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV55731204; called by muse, mutect2, varscan2
- DEFB129 | c.266C>A p.S89Y | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.275); catalogued as COSV55732042; called by muse, mutect2, varscan2
- DEK | c.322A>C p.N108H | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.027); catalogued as rs1468054729; called by muse, mutect2, varscan2
- DENND2C | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 40/173 reads (23%) | catalogued as COSV101283933; called by muse, mutect2, varscan2
- DENND4A | c.161C>A p.S54Y | Missense Mutation (SNP) | VAF 20/348 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71265893; called by muse, mutect2
- DESI2 | c.335C>A p.S112Y | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55642095; called by muse, mutect2, varscan2
- DEUP1 | c.1729C>A p.L577I | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769163934, COSV53213533; called by muse, mutect2, varscan2
- DHCR7 | c.645C>A p.F215L | Missense Mutation (SNP) | VAF 78/291 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs773048017, COSV62794796, COSV62796954; called by muse, mutect2, varscan2
- DHPS | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs200920073, COSV99269769; called by muse, mutect2, varscan2
- DHRS12 | c.575G>T p.R192I (on ENST00000444610 / NM_001377930.1; = p.R143I on NM_024705.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/199 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs142259693, COSV54470731; called by muse, mutect2, varscan2
- DHRS9 | c.69G>T p.K23N | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV59139491; called by muse, mutect2, varscan2
- DHTKD1 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs367981696; called by muse, mutect2, varscan2
- DHX29 | c.2891C>A p.S964Y | Missense Mutation (SNP) | VAF 60/239 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52420756; called by muse, mutect2, varscan2
- DHX40 | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 19/84 reads (23%) | catalogued as COSV99233362; called by muse, mutect2, varscan2
- DHX57 | c.1385C>A p.S462Y | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as COSV54885458, COSV54888213; called by muse, mutect2, varscan2
- DIAPH3 | c.2131G>T p.E711* (on ENST00000400324 / NM_001042517.2; = p.E448* on NM_030932.3) | Nonsense Mutation (SNP) | VAF 55/181 reads (30%) | catalogued as COSV57372625; called by muse, mutect2, varscan2
- DIAPH3 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 47/215 reads (22%) | catalogued as COSV57381039; called by muse, mutect2, varscan2
- DLAT | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 36/394 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs140603763, COSV54773214; called by muse, mutect2
- DLG5 | c.4402G>A p.D1468N | Missense Mutation (SNP) | VAF 20/225 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.899); catalogued as rs148449267; called by muse, mutect2
- DLL3 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 108/420 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs770966935, COSV52693963; called by muse, mutect2, varscan2
- DLX6 | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 78/278 reads (28%) | catalogued as COSV50294027; called by muse, mutect2, varscan2
- DMBT1 | c.4949G>A p.R1650Q (on ENST00000338354 / NM_001377530.1; = p.R893Q on NM_004406.3) | Missense Mutation (SNP) | VAF 171/318 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs775509248, COSV57537673, COSV57538240; called by muse, mutect2, varscan2
- DMD | c.10160C>T p.A3387V | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs202219782, COSV100626748; called by muse, mutect2, varscan2
- DMD | c.7143G>T p.E2381D | Missense Mutation (SNP) | VAF 70/395 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV58932132; called by muse, varscan2
- DMD | c.5899C>T p.R1967* | Nonsense Mutation (SNP) | VAF 20/91 reads (22%) | catalogued as rs128626249, CM087401, CM930194, COSV63737423; ClinVar: conflicting interpretations of pathogenicity / pathogenic; called by muse, mutect2, varscan2
- DMD | c.5476G>T p.E1826* | Nonsense Mutation (SNP) | VAF 62/296 reads (21%) | catalogued as CM096756, COSV63782395; called by muse, mutect2, varscan2
- DMXL1 | c.4018C>T p.R1340W | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs993973809, COSV60703916, COSV60705722; called by muse, mutect2, varscan2
- DNAAF1 | c.1698+8T>C | Splice Region (SNP) | VAF 74/323 reads (23%) | catalogued as rs1186759315; called by muse, mutect2, varscan2
- DNAH10 | c.4887C>A p.F1629L (on ENST00000409039; = p.F1568L on NM_207437.3) | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as rs766108846; called by muse, mutect2, varscan2
- DNAH11 | c.8534G>A p.R2845Q | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs372633683, COSV100179874; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH12 | c.9100C>T p.R3034W (on ENST00000351747; = p.R3902W on NM_001366028.2) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61054804; called by muse, mutect2, varscan2
- DNAH17 | c.6802G>A p.D2268N | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373616933; called by muse, mutect2, varscan2
- DNAH2 | c.11027G>A p.R3676H | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs142766785; called by muse, mutect2
- DNAH3 | c.8081C>T p.A2694V | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs372944277, COSV99764565; called by muse, mutect2, varscan2
- DNAH3 | c.4822T>C p.S1608P | Missense Mutation (SNP) | VAF 78/354 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1271808227; called by muse, mutect2, varscan2
- DNAH3 | c.1946G>T p.R649I | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.052); catalogued as rs188652923, COSV99770280; called by muse, mutect2, varscan2
- DNAH5 | c.9715G>A p.D3239N | Missense Mutation (SNP) | VAF 63/236 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as rs531401316, COSV54208820; called by muse, mutect2, varscan2
- DNAH5 | c.6619G>T p.D2207Y | Missense Mutation (SNP) | VAF 68/270 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54203010; called by muse, mutect2, varscan2
- DNAH5 | c.5425G>A p.A1809T | Missense Mutation (SNP) | VAF 68/290 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs758513686, COSV54205216; ClinVar: uncertain significance; called by muse, varscan2
- DNAH7 | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 12/59 reads (20%) | catalogued as rs779771239, COSV56751443; called by muse, mutect2
- DNAH8 | c.7649G>A p.G2550E | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59422807; called by muse, mutect2
- DNAH8 | c.10593G>T p.K3531N | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs778934662, COSV59443201, COSV99046881; called by muse, mutect2, varscan2
- DNAH8 | c.12781G>T p.E4261* | Nonsense Mutation (SNP) | VAF 12/59 reads (20%) | catalogued as rs1444174890, COSV100544328, COSV59470807; called by muse, mutect2, varscan2
- DNAI1 | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 75/302 reads (25%) | catalogued as COSV54282094; called by muse, mutect2, varscan2
- DNAI3 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.216); catalogued as rs370422920, COSV54002296; called by muse, mutect2, varscan2
- DNAJA2 | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 15/69 reads (22%) | catalogued as COSV57695109; called by muse, mutect2, varscan2
- DNAJC13 | c.2237G>A p.R746Q | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1232607951, COSV53447059; called by muse, mutect2, varscan2
- DNAJC24 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.878); catalogued as COSV71938535; called by muse, mutect2, varscan2
- DNAJC24 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 23/105 reads (22%) | catalogued as COSV101231528; called by muse, mutect2, varscan2
- DNAJC28 | c.937G>T p.D313Y | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs762955572; called by muse, mutect2, varscan2
- DNHD1 | c.2630C>T p.S877L | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs780428135, COSV54440518; called by muse, mutect2, varscan2
- DNMT1 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 73/253 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61577672; called by muse, mutect2, varscan2
- DNMT3B | c.2358C>A p.N786K | Missense Mutation (SNP) | VAF 70/300 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs868828837; called by muse, mutect2, varscan2
- DNPH1 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs112399499, COSV99334862; called by muse, mutect2, varscan2
- DNTT | c.1132G>T p.D378Y | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64523574; called by muse, mutect2
- DOCK1 | c.2559T>C p.H853= | Splice Region (SNP) | VAF 39/172 reads (23%) | catalogued as rs376145835; called by muse, mutect2, varscan2
- DOCK3 | c.1882C>T p.R628W | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs375482937; called by muse, mutect2, varscan2
- DOCK6 | c.4501C>T p.R1501C | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1268018171; called by muse, mutect2
- DOCK6 | c.2181C>A p.F727L | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs773582745, COSV99370834; called by muse, mutect2, varscan2
- DOCK7 | c.5797G>A p.D1933N (on ENST00000635253 / NM_001367561.1; = p.D1902N on NM_033407.3) | Missense Mutation (SNP) | VAF 58/260 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1363874427; called by muse, mutect2, varscan2
- DOCK7 | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 71/195 reads (36%) | catalogued as COSV52019199; called by muse, mutect2, varscan2
- DOCK8 | c.5287C>T p.R1763* | Nonsense Mutation (SNP) | VAF 110/471 reads (23%) | catalogued as rs1564072946, COSV66624313, COSV66625380; called by muse, mutect2, varscan2
- DOCK9 | c.317G>A p.S106N (on ENST00000376460 / NM_001366676.2; = p.S107N on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/240 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.075); catalogued as COSV59642926; called by muse, mutect2, varscan2
- DOK5 | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 49/194 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.885); catalogued as rs142008881, COSV52817161; called by muse, mutect2, varscan2
- DOP1A | c.44G>A p.R15K | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV52712295; called by muse, mutect2, varscan2
- DPP8 | c.826G>T p.E276* (on ENST00000341861 / NM_001320875.2; = p.E260* on NM_017743.6) | Nonsense Mutation (SNP) | VAF 45/214 reads (21%) | catalogued as COSV55676443; called by muse, mutect2, varscan2
- DPYD | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 37/152 reads (24%) | catalogued as rs1411354209, COSV64616278; called by muse, mutect2, varscan2
- DPYSL3 | c.1020G>T p.Q340H | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as COSV58323550; called by muse, mutect2, varscan2
- DRC1 | c.1135C>A p.Q379K | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs1178048254; called by muse, mutect2
- DSC3 | c.1231G>T p.E411* | Nonsense Mutation (SNP) | VAF 18/73 reads (25%) | catalogued as COSV64573854; called by muse, mutect2, varscan2
- DSCAM | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 55/514 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV68026184; called by muse, mutect2, varscan2
- DSEL | c.513G>T p.E171D | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.325); catalogued as COSV59490624; called by muse, mutect2, varscan2
- DSG1 | c.2669C>T p.S890L | Missense Mutation (SNP) | VAF 65/305 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as rs1326282747, COSV57135104; called by muse, mutect2, varscan2
- DSG3 | c.2813C>T p.S938L | Missense Mutation (SNP) | VAF 60/215 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV99934643; called by muse, mutect2, varscan2
- DSG4 | c.2519T>G p.F840C | Missense Mutation (SNP) | VAF 64/230 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746008339; called by muse, mutect2, varscan2
- DSPP | c.614G>T p.R205I | Missense Mutation (SNP) | VAF 76/309 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.036); catalogued as COSV99217032; called by muse, mutect2, varscan2
- DSPP | c.3499G>A p.D1167N | Missense Mutation (SNP) | VAF 156/704 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.983); catalogued as rs1431522740; called by muse, varscan2
- DST | c.8782G>A p.E2928K | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.242); catalogued as COSV55014110; called by muse, mutect2, varscan2
- DST | c.7241C>A p.S2414Y | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs758168314; called by muse, mutect2, varscan2
- DTHD1 | c.492G>T p.K164N (on ENST00000456874; = p.K289N on NM_001170700.3) | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1486170259; called by mutect2, varscan2
- DTX1 | c.1189C>T p.R397* | Nonsense Mutation (SNP) | VAF 27/110 reads (25%) | catalogued as rs747945791, COSV57496012; called by muse, mutect2, varscan2
- DTX3L | c.1008G>T p.E336D | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.236); catalogued as COSV99950069; called by muse, mutect2, varscan2
- DYM | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV53988110; called by muse, mutect2
- DYRK1A | c.1514C>T p.S505L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.31); catalogued as rs759594322; called by muse, mutect2, varscan2
- DYRK1B | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 76/293 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as COSV55683302; called by muse, mutect2, varscan2
- DZIP1 | c.1783C>T p.R595* (on ENST00000347108; = p.R576* on NM_014934.5) | Nonsense Mutation (SNP) | VAF 18/94 reads (19%) | catalogued as rs756109756, COSV61263776; called by muse, mutect2, varscan2
- DZIP1L | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770850434, COSV100551433; called by muse, mutect2, varscan2
- DZIP3 | c.1287G>T p.K429N | Missense Mutation (SNP) | VAF 23/221 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.544); catalogued as COSV64311409; called by muse, mutect2, varscan2
- ECD | c.1026G>T p.K342N | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as COSV65898745, COSV65900909; called by muse, mutect2, varscan2
- ECPAS | c.1136+1G>A p.X379_splice | Splice Site (SNP) | VAF 11/50 reads (22%) | catalogued as COSV52197590; called by muse, mutect2, varscan2
- ECRG4 | c.83G>A p.G28D | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs867805919; called by muse, mutect2, varscan2
- ECRG4 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs769838546, COSV53000263; called by muse, mutect2, varscan2
- EDA | c.796C>A p.L266I | Missense Mutation (SNP) | VAF 103/392 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100999709; called by muse, varscan2
- EEA1 | c.2148G>T p.E716D | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.97); catalogued as rs1173179560; called by muse, mutect2, varscan2
- EEF2K | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 71/258 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1283551467; called by muse, mutect2, varscan2
- EFCAB2 | c.622C>T p.R208* (on ENST00000366522; = p.R72* on NM_032328.3) | Nonsense Mutation (SNP) | VAF 25/147 reads (17%) | catalogued as rs764978665, COSV63655299; called by muse, varscan2
- EFCAB5 | c.659G>A p.R220K | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1318853288; called by muse, mutect2, varscan2
- EFEMP1 | c.948C>A p.F316L | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV100816870; called by muse, mutect2, varscan2
- EHMT1 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 64/344 reads (19%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs763562241, COSV58371181; called by muse, mutect2, varscan2
- EID3 | c.698G>T p.R233L | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV61597378; called by muse, mutect2, varscan2
- EIF4E2 | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs377735542, COSV51471158; called by muse, mutect2, varscan2
- EIF4G3 | c.2275C>T p.R759* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as COSV51677587; called by muse, mutect2, varscan2
- ELAVL2 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 82/369 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56360312; called by muse, mutect2, varscan2
- ELL | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53216196; called by muse, mutect2, varscan2
- ELL2 | c.1292C>A p.S431Y | Missense Mutation (SNP) | VAF 42/288 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV99427529; called by muse, mutect2, varscan2
- ELOVL1 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 68/289 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs746646318; called by muse, mutect2, varscan2
- EMC2 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as rs1030080319; called by muse, mutect2, varscan2
- EMC7 | c.420G>T p.M140I | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV56628301; called by muse, mutect2, varscan2
- EMD | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as CD078077, COSV63962464; called by muse, mutect2, varscan2
- EMG1 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99780921; called by muse, mutect2, varscan2
- EMILIN1 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as rs569070507, COSV99566536; called by muse, mutect2, varscan2
- EML4 | c.649G>T p.D217Y | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs766060311; called by mutect2, varscan2
- EML5 | c.1583A>G p.Y528C | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); catalogued as rs750776675; called by muse, mutect2, varscan2
- EML6 | c.2144G>A p.R715Q | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as rs368082723; called by muse, mutect2, varscan2
- EMSY | c.2142G>T p.Q714H | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.592); catalogued as COSV58259551; called by muse, mutect2, varscan2
- ENOX1 | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 78/303 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1284633061, COSV54898039; called by muse, mutect2, varscan2
- ENOX2 | c.1501G>T p.E501* (on ENST00000338144 / NM_001382520.1; = p.E472* on NM_006375.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | catalogued as COSV57654358; called by muse, mutect2, varscan2
- ENPEP | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 108/419 reads (26%) | catalogued as rs143343563, COSV54448047; called by muse, mutect2, varscan2
- ENPEP | c.2061G>T p.E687D | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs763798263, COSV54456976; called by muse, varscan2
- ENPEP | c.2449G>T p.E817* | Nonsense Mutation (SNP) | VAF 26/108 reads (24%) | catalogued as COSV54450303; called by muse, mutect2, varscan2
- ENPP5 | c.101C>A p.S34Y | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57908214; called by muse, mutect2, varscan2
- ENTPD1 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 86/385 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.595); catalogued as rs375311388; called by muse, mutect2, varscan2
- EP400 | c.2635G>T p.E879* | Nonsense Mutation (SNP) | VAF 23/129 reads (18%) | catalogued as COSV57762391, COSV57787435; called by muse, mutect2, varscan2
- EP400 | c.5132A>C p.K1711T | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV57764009; called by muse, mutect2
- EPG5 | c.5307C>T p.F1769= | Splice Region (SNP) | VAF 28/118 reads (24%) | catalogued as rs369940983; called by muse, mutect2, varscan2
- EPHA1 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 85/368 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51970732; called by muse, mutect2, varscan2
- EPHA10 | c.713G>A p.G238E | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57626066; called by muse, mutect2, varscan2
- EPHA7 | c.1446G>T p.E482D | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV65193862; called by muse, mutect2
- EPHB1 | c.281G>T p.R94I | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV67662008; called by muse, mutect2, varscan2
- EPHX4 | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 7/84 reads (8%) | catalogued as COSV64889320; called by muse, mutect2
- ERC2 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as rs747730160, COSV55605679; called by muse, mutect2, varscan2
- ERCC6L2 | c.3389C>T p.S1130L | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs377159573; called by muse, mutect2, varscan2
- ERICH3 | c.3814G>T p.E1272* | Nonsense Mutation (SNP) | VAF 34/374 reads (9%) | catalogued as COSV58607176; called by muse, mutect2
- ERICH3 | c.3385G>A p.E1129K | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.209); catalogued as rs866558257, COSV58599808; called by muse, mutect2, varscan2
- ERMAP | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as rs771684891, COSV60275387; called by muse, mutect2, varscan2
- ERMP1 | c.1535G>T p.R512I | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs374389047; called by muse, varscan2
- ERVFRD-1 | c.295G>T p.D99Y | Missense Mutation (SNP) | VAF 65/298 reads (22%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.959); catalogued as rs758368739; called by muse, mutect2, varscan2
- ESR1 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs1207112399, COSV52805223; called by muse, mutect2
- ESYT2 | c.1726C>T p.R576* (on ENST00000613624; = p.R500* on NM_020728.3) | Nonsense Mutation (SNP) | VAF 30/151 reads (20%) | catalogued as COSV51756194; called by muse, mutect2, varscan2
- ETFRF1 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 38/147 reads (26%) | catalogued as COSV61477538; called by muse, mutect2, varscan2
- EXO1 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 31/229 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs567681802, COSV62217034; called by muse, mutect2, varscan2
- EXOC6 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1313401416, COSV53319946; called by muse, mutect2, varscan2
- EXOC6 | c.2154C>A p.F718L | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV53318681, COSV53332487; called by muse, mutect2, varscan2
- EXPH5 | c.3196A>G p.M1066V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1488275654; called by muse, mutect2, varscan2
- EXTL1 | c.1693C>T p.L565F | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV65332122; called by muse, mutect2, varscan2
- EYA1 | c.956C>A p.S319Y | Missense Mutation (SNP) | VAF 125/404 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100378213, COSV58161198; called by muse, mutect2, varscan2
- EYS | c.4643C>A p.S1548Y | Missense Mutation (SNP) | VAF 73/233 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV58196666; called by muse, mutect2, varscan2
- EYS | c.2847-1G>T p.X949_splice | Splice Site (SNP) | VAF 28/146 reads (19%) | catalogued as rs1368916345, CS102750; called by muse, mutect2, varscan2
- EYS | c.2425G>T p.E809* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV65463387, COSV65490355; called by muse, mutect2, varscan2
- F13B | c.1769A>C p.E590A | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV66372934; called by muse, mutect2, varscan2
- F5 | c.6163C>T p.R2055* | Nonsense Mutation (SNP) | VAF 73/287 reads (25%) | catalogued as rs199690772, COSV63124791; called by muse, mutect2, varscan2
- F7 | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.869); catalogued as rs149779477; called by muse, mutect2, varscan2
- F8 | c.6243G>A p.W2081* | Nonsense Mutation (SNP) | VAF 26/241 reads (11%) | catalogued as CM067386, CM088372; called by muse, mutect2
- F8 | c.2258A>C p.N753T | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV64273405; called by muse, mutect2, varscan2
- F8 | c.2006C>A p.S669Y | Missense Mutation (SNP) | VAF 58/245 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM129741, CM138664; called by muse, mutect2, varscan2
- FAM107A | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.103); catalogued as rs960131861; called by muse, mutect2, varscan2
- FAM118B | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759288635; called by muse, mutect2
- FAM133A | c.317C>A p.S106Y | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.571); catalogued as rs1293865237; called by muse, mutect2, varscan2
- FAM13A | c.2896C>T p.R966* | Nonsense Mutation (SNP) | VAF 16/86 reads (19%) | catalogued as rs751043687; called by muse, mutect2, varscan2
- FAM13B | c.1657C>T p.R553* | Nonsense Mutation (SNP) | VAF 27/105 reads (26%) | catalogued as rs756297490, COSV50365444; called by muse, mutect2, varscan2
- FAM162B | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 92/316 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV63920195; called by muse, mutect2, varscan2
- FAM178B | c.649C>T p.R217* | Nonsense Mutation (SNP) | VAF 33/143 reads (23%) | catalogued as rs746051795, COSV100014585; called by muse, mutect2, varscan2
- FAM204A | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 23/86 reads (27%) | catalogued as COSV64987858; called by muse, mutect2, varscan2
- FAM205A | c.2720C>T p.P907L | Missense Mutation (SNP) | VAF 63/269 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1421048907; called by muse, mutect2, varscan2
- FAM25C | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.81); catalogued as rs879960516; called by mutect2, varscan2
- FAM81A | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs775796209, COSV99893428; called by muse, mutect2, varscan2
- FAM91A1 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 23/255 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58236076; called by muse, mutect2
- FANCA | c.559G>A p.V187I | Missense Mutation (SNP) | VAF 98/421 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs761538996, COSV66881439; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FANCC | c.1081C>T p.R361W | Missense Mutation (SNP) | VAF 104/425 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs768508859, COSV56657024; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FANCD2 | c.1282C>A p.L428I | Missense Mutation (SNP) | VAF 59/539 reads (11%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.58); catalogued as COSV55036352; called by muse, mutect2, varscan2
- FANCD2 | c.4286C>A p.S1429Y | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV55038248; called by muse, mutect2
- FANCE | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376243211; called by muse, mutect2, varscan2
- FAP | c.879C>A p.F293L | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1249796784; called by muse, mutect2, varscan2
- FARP2 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1176974527, COSV99883813; called by muse, mutect2, varscan2
- FAT1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as rs368175691, COSV71676688; called by muse, mutect2, varscan2
- FAT1 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 39/137 reads (28%) | catalogued as COSV71672617; called by muse, mutect2, varscan2
- FAT3 | c.496A>C p.T166P | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV53123966; called by muse, mutect2, varscan2
- FAT3 | c.652C>T p.R218* | Nonsense Mutation (SNP) | VAF 43/186 reads (23%) | catalogued as rs1222689483, COSV53081376; called by muse, mutect2, varscan2
- FAT3 | c.8024C>T p.S2675L | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV53094091, COSV53094990; called by muse, mutect2, varscan2
- FAT3 | c.10452C>A p.F3484L | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53095778; called by muse, mutect2
- FAT4 | c.10031G>A p.R3344Q | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs769028469, COSV58676528; called by muse, mutect2, varscan2
- FBN1 | c.4429G>A p.E1477K | Missense Mutation (SNP) | VAF 143/504 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.988); catalogued as rs869025407, CM972810, COSV57312455; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBN2 | c.6583C>T p.R2195C | Missense Mutation (SNP) | VAF 14/317 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs886059896, COSV52511930; ClinVar: uncertain significance; called by muse, mutect2
- FBXL7 | c.125A>G p.E42G | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as COSV100310359; called by muse, mutect2
- FBXO27 | c.657C>A p.F219L | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.376); catalogued as COSV53072881, COSV53073029; called by muse, mutect2, varscan2
- FBXW10 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.425); catalogued as rs752194941, COSV57320212; called by muse, mutect2, varscan2
- FBXW7 | c.817G>T p.E273* (on ENST00000281708 / NM_001349798.2; = p.E193* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 23/121 reads (19%) | catalogued as COSV99660049, COSV99662586; called by muse, mutect2, varscan2
- FCGR1A | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 81/400 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs374578876; called by muse, mutect2, varscan2
- FCGR2A | c.495C>A p.F165L (on ENST00000271450 / NM_001136219.3; = p.F164L on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 119/437 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV54838164; called by muse, mutect2, varscan2
- FCRL5 | c.1044G>T p.E348D | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.891); catalogued as COSV62514146; called by muse, mutect2, varscan2
- FCRLA | c.989C>A p.S330Y (on ENST00000367959; = p.S307Y on NM_032738.4) | Missense Mutation (SNP) | VAF 13/319 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.325); catalogued as COSV52688682; called by muse, mutect2
- FECH | c.315-7G>T | Splice Region (SNP) | VAF 29/212 reads (14%) | catalogued as rs755675064; called by muse, mutect2, varscan2
- FER | c.24G>T p.K8N | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.21); catalogued as COSV55297927; called by muse, varscan2
- FER | c.87G>T p.K29N | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55284488; called by muse, varscan2
- FER | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | catalogued as COSV55287737; called by muse, mutect2, varscan2
- FERD3L | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 60/219 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51762163, COSV51764328; called by muse, mutect2, varscan2
- FERD3L | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as rs766581757, COSV51761566; called by muse, mutect2, varscan2
- FGD3 | c.1544C>T p.S515L | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs367688293; called by muse, mutect2, varscan2
- FGD4 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 67/263 reads (25%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as rs540449675, COSV99847534; called by muse, mutect2, varscan2
- FGD6 | c.3641C>T p.S1214L | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as rs751711117; called by muse, varscan2
- FGF12 | c.349G>A p.A117T (on ENST00000454309 / NM_021032.5; = p.A55T on NM_004113.6) | Missense Mutation (SNP) | VAF 57/232 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.856); catalogued as rs1352370070; called by muse, mutect2, varscan2
- FGF13 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.341); catalogued as rs1207647802; called by muse, mutect2, varscan2
- FH | c.976G>A p.G326R | Missense Mutation (SNP) | VAF 62/253 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553341038; ClinVar: uncertain significance; called by muse, varscan2
- FILIP1L | c.3272G>A p.R1091Q (on ENST00000354552 / NM_182909.3; = p.R851Q on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs377075355, COSV58765934, COSV58772257; called by muse, mutect2, varscan2
- FKTN | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 140/553 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs765934383, COSV56308764; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLG2 | c.1643C>A p.S548Y | Missense Mutation (SNP) | VAF 127/473 reads (27%) | SIFT tolerated (0.9); PolyPhen benign (0.11); catalogued as COSV66170628; called by muse, mutect2, varscan2
- FMN1 | c.2914C>T p.R972* (on ENST00000616417 / NM_001277313.2; = p.R749* on NM_001103184.4) | Nonsense Mutation (SNP) | VAF 55/196 reads (28%) | catalogued as rs375237808; called by muse, mutect2, varscan2
- FMN2 | c.2228C>T p.S743L | Missense Mutation (SNP) | VAF 81/304 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1397813836, COSV60424392; called by muse, mutect2, varscan2
- FMR1 | c.755C>A p.A252D | Missense Mutation (SNP) | VAF 69/237 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.026); catalogued as COSV54424732; called by muse, mutect2, varscan2
- FNDC5 | c.572C>A p.T191N | Missense Mutation (SNP) | VAF 76/263 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); catalogued as COSV65105708; called by muse, mutect2, varscan2
- FNIP1 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 64/244 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57194268, COSV57197482; called by muse, mutect2, varscan2
- FNIP2 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1256373490, COSV52436862; called by muse, mutect2, varscan2
- FOXJ2 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs201863216; called by muse, mutect2, varscan2
- FOXJ3 | c.1402C>T p.R468* | Nonsense Mutation (SNP) | VAF 36/174 reads (21%) | catalogued as COSV62362613; called by muse, mutect2, varscan2
- FOXP2 | c.1081G>T p.G361* | Nonsense Mutation (SNP) | VAF 71/268 reads (26%) | catalogued as COSV63491740; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1070C>A p.S357Y | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV58569118; called by muse, varscan2
- FREM1 | c.6298C>T p.R2100W | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as rs200489692, COSV66524547; called by muse, mutect2, varscan2
- FREM2 | c.4675G>A p.E1559K | Missense Mutation (SNP) | VAF 51/223 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.342); catalogued as rs267603820, COSV54839837; called by muse, mutect2, varscan2
- FRG1BP | n.415A>T | Splice Region (SNP) | VAF 14/179 reads (8%) | catalogued as rs1484950580; called by muse, mutect2
- FRMD7 | c.65C>A p.S22* | Nonsense Mutation (SNP) | VAF 70/304 reads (23%) | catalogued as COSV53746063, COSV53748789; called by muse, varscan2
- FRMPD2 | c.2560G>T p.E854* | Nonsense Mutation (SNP) | VAF 26/122 reads (21%) | catalogued as COSV100564016, COSV59720132; called by muse, mutect2, varscan2
- FRRS1 | c.705G>T p.M235I | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as COSV99790060; called by muse, mutect2, varscan2
- FRY | c.27C>A p.F9L | Missense Mutation (SNP) | VAF 18/412 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV66578791; called by muse, mutect2
- FSCN3 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 62/271 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs768392595; called by muse, mutect2, varscan2
- FSHR | c.491C>A p.S164Y | Missense Mutation (SNP) | VAF 81/334 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1213765229, COSV58622104; called by muse, mutect2, varscan2
- FSHR | c.102G>T p.E34D | Missense Mutation (SNP) | VAF 102/389 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV58627673; called by muse, mutect2, varscan2
- FSIP2 | c.7338G>T p.K2446N | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV58096759; called by muse, mutect2, varscan2
- FSIP2 | c.18370G>A p.E6124K | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58078679; called by muse, varscan2
- FTSJ3 | c.2348G>A p.R783Q | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs776780004, COSV63790970; called by muse, mutect2, varscan2
- G2E3 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 24/89 reads (27%) | catalogued as COSV52838305; called by muse, mutect2, varscan2
- G2E3 | c.1398C>A p.F466L | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV52841849; called by muse, mutect2, varscan2
- G6PD | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 74/315 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as COSV63705051; called by muse, mutect2, varscan2
- GABRA3 | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as COSV100942833; called by muse, mutect2, varscan2
- GABRE | c.366C>A p.F122L | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.069); catalogued as rs1430667310; called by muse, mutect2
- GABRE | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 81/354 reads (23%) | catalogued as COSV99059201; called by muse, mutect2, varscan2
- GABRG1 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs940269899, COSV54951321; called by muse, mutect2, varscan2
- GABRR2 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs148209347; called by muse, mutect2, varscan2
- GALNT15 | c.195G>T p.Q65H | Missense Mutation (SNP) | VAF 17/267 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV60215834; called by muse, mutect2
- GALNT15 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 53/229 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as rs773344258, COSV60220073; called by muse, mutect2, varscan2
- GALNT2 | c.1185C>A p.F395L | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs754934176, COSV64194651, COSV64197639; called by muse, mutect2, varscan2
- GALNT8 | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV52897342; called by muse, mutect2, varscan2
5,109 further variants in this file (3,447 protein-altering or splice-affecting, 921 silent, 741 other) are not listed here.
